Gene-level copy-number profile of tumor specimen TCGA-28-1756-01C from TCGA case TCGA-28-1756, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 78.4 years (28,649 days).
Specimen TCGA-28-1756-01C: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.015af4f1-9ae8-4dd0-ac33-7a3ed2f57a92.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-28-1756-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/2cef849a-b368-48b8-9370-78d997972f21

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 21; copy number 1: 31; copy number 2: 8,280; copy number 3: 1,711; copy number 4: 48,345; copy number 5: 359; copy number 6: 1,068.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-28-1756-01): tumor purity 0.78, ploidy 1.89, whole-genome doublings 0 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 13. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
